Somatic mutation profile of tumor specimen BA2296D (aliquot aq-BA2296D) from BEATAML1.0 case 2497, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.0 years (16,806 days).
Specimen BA2296D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9a262ff-c043-45aa-882b-aff1d9b98dd5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2075D (Solid Tissue Normal), aliquot aq-BA2075D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cd8897e-7666-41f4-b66c-bb5cba418dee

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA10 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs368512398; called by muse, mutect2, varscan2
- GATA2 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62003239, COSV62003719, COSV62003772; called by muse, mutect2
- GRAMD4 | c.469C>A p.R157S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV63029822; called by muse, mutect2
- HK3 | c.193C>G p.Q65E | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs758607126, COSV99457924; called by muse, varscan2
- IRF8 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51899453; called by muse, mutect2
- JUP | c.1567G>T p.V523F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.663); catalogued as COSV60279446; called by muse, mutect2
- SHROOM1 | c.186C>A p.Y62* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs1486859975; called by muse, varscan2
- CEBPA | c.291dup p.T98Hfs*10 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | called by mutect2, varscan2
- IMPG1 | c.867-1G>C p.X289_splice | Splice Site (SNP) | VAF 50/178 reads (28%) | called by muse, mutect2, varscan2
- TDRD15 | c.3572C>A p.S1191Y | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.311); called by muse, mutect2
- CCR9 | c.423C>T p.S141= (on ENST00000357632 / NM_031200.3; = p.S129= on NM_006641.4) | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs201764174; called by muse, mutect2, varscan2
